FM case AD1522 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Spinal cord, cranial nerves, and other parts of central nervous system.
https://portal.gdc.cancer.gov/cases/dc995ec4-a330-41e0-813a-24f194f7d8fb

Female, 31.7 years: Ependymoma, NOS (ICD-O-3 9391/3) of the nervous system; metastasis biopsied or resected from the spleen. Tumor nuclei on the sequenced sample's slide: 70% (pathologist estimate recorded by GDC). Sample type: Metastatic.
